Surgical pathology report (de-identified scan), TCGA case TCGA-W9-A837, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Kansas, specimen TCGA-W9-A837-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

NAME:

MR #:

BILLING #:

LOCATION:

AGE:

SEX: M

DOB:

PHYSICIAN:

COPY TO:

SURG PATH #:

SPECIMEN CLASS:

ALT ID #:

DATE OF PROCEDURE:

DATE RECEIVED:

TIME RECEIVED:

DATE OF REPORT:

DATE OF PRINTING:

Material Received:

- A: right frontal brain lesion
- B: anterior wall
- C: lateral wall
- D: posterior wall
- E: medial wall
- F: right frontal brain mass

ICD O-3
Oligodendroglioma, grade II 9450/3
Site: Brain, supratentorial NOS C71.0
path
Brain, frontal lobe, C71.1
11/16/14

History:

year-old man with a history of a right frontal oligodendroglioma, WHO grade II with deletions of 1p/19q. When compared to multiple prior studies dating back to and there has been slow, steady slight increase in size of a 0.6 cm enhancing lesion along the superomedial margin of the operative cavity.

Final Diagnosis:

Craniotomy for resection of tumor:

- A. (Brain), "right frontal brain lesion": OLIGODENDROGLIOMA, WHO GRADE II (OF III)
- B. (Brain), "anterior wall": OLIGODENDROGLIOMA
- C. (Brain), "lateral wall": OLIGODENDROGLIOMA
- D. (Brain), "posterior wall": OLIGODENDROGLIOMA
- E. (Brain), "medial wall": OLIGODENDROGLIOMA
- F. (Brain), "right frontal brain mass": OLIGODENDROGLIOMA, WHO GRADE II (OF III)—see comment

Comment:

Although a few areas of tumor appear slightly more cellular than others, no features to support progression to a higher grade are identified in these sections. Only one mitotic figure is recognized. Some leptomeningeal vascular tissue, bearing a resemblance to an angioma, is noted in (A), but no microvascular proliferation is detected in the current sections of tumor. Ongoing regular imaging surveillance is suggested.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

MR #:

Page 1 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Interpreted by:

MD, Attending Physician

Microscopic Description:

The tumor has the well-differentiated appearance of oligodendroglioma, complete with perinuclear haloes, a delicate capillary network, and even spacing of cells, in many areas. No calcifications are noted. A single vessel with some increase in endothelial cells is noted (section D2); microvascular proliferation is not identified. Necrosis is not present in these sections. A single mitotic figure is detected (F3) in an area of mild vascular hypertrophy. More closely packed cells with slightly more atypia are seen (F5), and a focus of bluer, more atypical cells is noted focally in (A2). Infrequent p53 labeling of cells is noted (F5). MIB-1, performed on several sections (F1, F5, A2, D2), stains relatively low numbers of nuclei. In sections from (A), several highly vascular foci of superficial leptomeningeal tissue include back-to-back small vessels.

Gross Description:

A. Received fresh labeled with the patient's name and "right frontal brain lesion" is a 2.0 x 1.7 x 0.2 to 0.3 cm piece of reddish gray matter and a 2.3 x 1.8 x 1.0 cm piece of gray-white matter. A squash is made from the first piece of tissue, and a piece of the second piece of tissue is submitted as A1FS for frozen and subsequent permanent sections. The remainder is entirely submitted in cassettes A2 through A4.

B. Received fresh labeled with the patient's name and "anterior wall" is a 0.8 x 0.6 x 0.4 cm irregular piece of white-tan tissue. Approximately 1/2 is submitted as B1FS for frozen and subsequent permanent sections. Squashes are made. The remainder of the tissue is entirely submitted in cassette B2.

C. Received fresh labeled with the patient's name and "lateral wall" is a 1.0 x 1.0 x 0.6 cm irregular piece of red-tan white matter. Approximately 1/2 is submitted as C1FS for frozen and permanent sections. Squashes are made. The remainder of the tissue is entirely submitted in cassette C2.

D. Received fresh labeled with the patient's name and "posterior wall" is a gray-white piece of tissue with an indistinct edge measuring 2.7 x 1.5 x 1.0 cm. One-half is submitted as D1FS for frozen and subsequent permanent sections. The remaining tissue is entirely submitted in cassette D2.

E. Received fresh labeled with the patient's name and "medial wall" is a 2.0 x 0.8 x 0.4 cm red-tan rubbery piece of tissue. One-half is submitted as E1FS for frozen and subsequent permanent sections. The remaining tissue is entirely submitted in cassette E2.

F. Received in formalin labeled with the patient's name and "right frontal brain mass" is a 4.5 x 4.2 x 1.6 cm aggregate of tan-white tissue fragments consistent with brain tissue. There are multiple areas of hemorrhage located within the tissue. There are also areas of softer tissue. Representative sections from throughout the specimen are submitted in cassettes F1 through F5.

MD, Attending Physician

Intraoperative Consultation:

A1FS, squash, "right frontal brain lesion":

Cellular glial neoplasm with oligodendroglial component, possibly mixed glioma. No necrosis or vascular proliferation in current sections

B1FS, squash, "anterior wall":

Tumor present with relatively spared cortical areas

C1FS, squash, "lateral wall":

Tumor present with relatively spared cortical areas

D1FS, squash, "posterior wall":

Solid tumor present

E1FS, squash, "medial wall":

Solid tumor present

MD, Attending Physician

If immunohistochemical stains and/or in situ hybridization are cited in this report, the performance characteristics were determined by the

Date of Printing:

MR #:

Page 2 of 3

SURGICAL PATHOLOGY REPORT

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

in compliance with CLIA'88 regulations. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the FDA. Known positive and negative control tissues demonstrate appropriate staining. This testing was developed by the
It has not been cleared or approved by the FDA. The FDA has determined that such clearance or approval is not necessary.

IH/PAH Inconsistency		✓

Date of Printing:

MR #:

Page 3 of 3

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 0a696f2f-4dd1-461a-a4a6-636877e2f2a4 (TCGA-W9-A837.278CE30B-6EAA-47C3-9D21-F3F7142852D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).